Somatic mutation profile of tumor specimen C3L-08257-02 (aliquot CPT0477470006) from CPTAC case C3L-08257, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 67.3 years (24,581 days).
Specimen C3L-08257-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79c5f3c2-e61a-4095-b3a3-3683763570aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08257-31 (Blood Derived Normal), aliquot CPT0475640003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/630d0bdf-fb3b-40aa-80f0-6004d38376b7

The open-access MAF lists 60 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Intron 3, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 43/274 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.294); catalogued as rs567923786; called by muse, mutect2, varscan2
- ADCY5 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 23/350 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs148824947; called by muse, mutect2
- API5 | c.679T>G p.F227V | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs773834543; called by muse, mutect2, varscan2
- BOD1L1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs768340636, COSV50012031; called by muse, mutect2, varscan2
- COL5A3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs563109290, COSV53409530; called by muse, mutect2, varscan2
- DAGLA | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); catalogued as rs1409547344, COSV57193994; called by muse, mutect2
- DSEL | c.1414A>C p.S472R | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100025940, COSV59489055; called by muse, mutect2, varscan2
- EPC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433910452, COSV53923041; called by muse, mutect2, varscan2
- HNMT | c.299-1G>C p.X100_splice | Splice Site (SNP) | VAF 26/192 reads (14%) | catalogued as rs201003656; called by muse, mutect2
- HOXA4 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 58/356 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs777227082; called by muse, mutect2, varscan2
- LOXHD1 | c.3659A>C p.K1220T | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56063150, COSV56074005; called by muse, mutect2, varscan2
- NAA11 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs754326300; called by muse, mutect2, varscan2
- NOMO1 | c.3517G>A p.A1173T | Missense Mutation (SNP) | VAF 18/463 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.906); catalogued as rs747125310; called by muse, mutect2
- NR2F1 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs1340248863; called by muse, mutect2
- NYAP1 | c.2221C>T p.L741F | Missense Mutation (SNP) | VAF 55/404 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1489750571; called by muse, mutect2, varscan2
- PLEKHG4B | c.2081C>T p.T694M (on ENST00000283426; = p.T1050M on NM_052909.5) | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1293340086, COSV52055347; called by muse, mutect2, varscan2
- SCN2A | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs755003900, COSV51839268; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAT5A | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1352317038; called by muse, mutect2, varscan2
- TUBGCP3 | c.2698del p.R900Gfs*110 | Frame Shift Del (DEL) | VAF 84/384 reads (22%) | catalogued as rs1176495652; called by mutect2, varscan2
- UHRF1 | c.971G>A p.R324Q (on ENST00000612630 / NM_001290050.1; = p.R337Q on NM_013282.4) | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1203961237; called by muse, mutect2
- UNC45B | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 45/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52096717; called by muse, mutect2
- ZNF382 | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53089342; called by muse, mutect2
- AJAP1 | c.808A>T p.R270W | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- AKAP13 | c.4832G>T p.G1611V (on ENST00000394518 / NM_007200.5; = p.G1615V on NM_006738.6) | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); called by mutect2, varscan2
- AKT3 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2
- CDV3 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- COL5A3 | c.3324_3331dup p.P1111Qfs*36 | Frame Shift Ins (INS) | VAF 38/310 reads (12%) | called by mutect2, varscan2
- DNAH17 | c.5366A>G p.H1789R | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH5 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 37/327 reads (11%) | called by muse, mutect2, varscan2
- GRB14 | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1159G>A p.D387N (on ENST00000485419 / NM_001197113.1; = p.D311N on NM_014575.3) | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITGAL | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP4K4 | c.3296T>G p.V1099G (on ENST00000347699 / NM_001242559.2; = p.V1017G on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NTRK3 | c.2023T>A p.F675I | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OTUD7A | c.1552G>A p.D518N (on ENST00000307050 / NM_001382637.1; = p.D511N on NM_130901.3) | Missense Mutation (SNP) | VAF 50/527 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSMD3 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRJ | c.2075del p.S692Yfs*10 | Frame Shift Del (DEL) | VAF 38/340 reads (11%) | called by mutect2, pindel, varscan2
- RAB3GAP1 | c.991_992insG p.F331Cfs*3 | Frame Shift Ins (INS) | VAF 17/182 reads (9%) | called by mutect2, pindel, varscan2
- RTN4R | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SEC24A | c.3191A>T p.N1064I | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SON | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- TERB1 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZMYM6 | c.1422C>G p.Y474* | Nonsense Mutation (SNP) | VAF 40/278 reads (14%) | called by muse, mutect2, varscan2
- ADGRE2 | c.1284T>C p.L428= | Silent (SNP) | VAF 64/365 reads (18%) | called by muse, mutect2, varscan2
- BPIFB3 | c.117C>T p.L39= | Silent (SNP) | VAF 35/326 reads (11%) | catalogued as rs763851993, COSV64957157; called by muse, mutect2
- CD1D | c.192C>A p.T64= | Silent (SNP) | VAF 62/420 reads (15%) | called by muse, mutect2, varscan2
- GRK1 | c.1293G>A p.L431= | Silent (SNP) | VAF 115/497 reads (23%) | called by muse, mutect2, varscan2
- IL3 | c.327C>T p.A109= | Silent (SNP) | VAF 42/334 reads (13%) | catalogued as rs139674576, COSV99735326; called by muse, mutect2, varscan2
- INTS2 | c.3090A>G p.A1030= | Silent (SNP) | VAF 30/224 reads (13%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.1671A>T p.A557= | Silent (SNP) | VAF 29/340 reads (9%) | called by muse, mutect2
- LRRN4 | c.1332C>T p.S444= | Silent (SNP) | VAF 46/443 reads (10%) | catalogued as rs755803768; called by muse, mutect2, varscan2
- MUC6 | c.2610C>T p.L870= | Silent (SNP) | VAF 76/540 reads (14%) | called by muse, mutect2, varscan2
- OR11H12 | c.312A>G p.K104= | Silent (SNP) | VAF 21/186 reads (11%) | called by mutect2, varscan2
- PHRF1 | c.3054C>T p.R1018= (on ENST00000264555 / NM_001286581.2; = p.R1017= on NM_020901.4) | Silent (SNP) | VAF 68/597 reads (11%) | called by muse, mutect2, varscan2
- UBR4 | c.8682C>T p.G2894= | Silent (SNP) | VAF 28/346 reads (8%) | called by muse, mutect2
- AL132655.6 | chr20:58839637 C>T | 5'Flank (SNP) | VAF 44/386 reads (11%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3759T>C | Intron (SNP) | VAF 42/380 reads (11%) | called by muse, mutect2, varscan2
- ZNF415 | c.136+41G>A | Intron (SNP) | VAF 39/360 reads (11%) | called by muse, mutect2, varscan2
- ZNF841 | c.-77-8534C>G | Intron (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
